Surgical pathology report (de-identified scan), TCGA case TCGA-A4-7287, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-7287-01A (Primary Tumor).

[page 1 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

LEFT KIDNEY AND URETER, NEPHRECTOMY:

- INVASIVE PAPILLARY UROTHELIAL CARCINOMA, HIGH-GRADE.
- ARISING IN AND CONFINED TO RENAL PELVIS/CALICES.
- SMALL FOCI OF INVASIVE CARCINOMA INVADING THE LAMINA PROPRIA.
- ADJACENT UROTHELIAL CARCINOMA IN SITU.
- MARGIN STATUS: NEGATIVE.
- VASCULAR, URETERAL, AND GEROTA'S FASCIA MARGIN ALL NEGATIVE.
- NO LYMPH NODES IDENTIFIED.
- BACKGROUND KIDNEY SHOWS PATCHY CHRONIC INTERSTITIAL NEPHRITIS.

PATHOLOGIC TUMOR STAGING SUMMARY:

- Histologic type and grade: Invasive (papillary) urothelial carcinoma, high-grade.
- Primary tumor: pT1.
- Regional lymph nodes: pNX.
- Distant metastasis: pMX.
- Stage: pI.
- Margin status: R0, negative.
- Lymphovascular and perineural invasion: Not identified.

COMMENT: Most of the tumor is non-invasive high-grade papillary urothelial carcinoma (3.7 cm in greatest dimension) but there are a few small foci of invasive urothelial carcinoma (invading the lamina propria of the papillary stalk, up to 1 mm). The diagnosis is called to [REDACTED]

[page 2 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, [REDACTED])

RENAL PELVIS:

Regional lymph nodes:

Procedure:

Specimen laterality:

Tumor size:

No nodes submitted or found.

Nephrectomy with partial ureterectomy.

Left.

3.7 x 3.2 x 3.2 cm (Most of which is non-invasive papillary carcinoma, with a few small foci of invasive carcinoma invading the lamina propria measuring up to 0.1 cm).

Histologic type:

Urothelial (transitional cell) carcinoma.

Associated epithelial lesions:

Background of non-invasive papillary urothelial carcinoma, high-grade.

Histologic grade:

High-grade.

Tumor configuration:

Papillary.

Margins:

Margins uninvolved by invasive carcinoma (closest margin is Gerota's fascia at 1 cm; tumor is 1.5 cm from renal hilar vascular margins).

Lymphovascular invasion:

Not identified.

PATHOLOGIC STAGING (no TNM descriptors):

Primary tumor:

pT1, tumor invades subepithelial connective tissue (lamina propria).

Regional lymph nodes:

pNX.

Distant metastasis:

pMX.

Additional pathologic findings:

Urothelial carcinoma in situ (high-grade intraurothelial neoplasia).

Inflammation/regenerative changes (patchy chronic interstitial nephritis).

[page 3 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

Left Kidney and Left Ureter

Clinical History/Operative Dx:

Left renal pelvic tumor

Gross Description:

The specimen is labeled left kidney and ureter and is received without fixative. It consists of a nephrectomy specimen with adherent long segment of ureter which weighs [REDACTED] [REDACTED]. The nephrectomy specimen measures 14 cm from superior to inferior, 7.5 cm from medial to lateral, and 5 cm from anterior to posterior. There is no grossly identifiable adrenal gland tissue. Along the anterior surface of the kidney is a 8 x 5.5 cm area of thin delicate adherent tissue suggestive of Gerota's fascia. At the hilum the renal artery and renal vein are identified. The vessels are opened and show no gross evidence of intraluminal tumor. Extending from the hilum of the kidney is a 26 cm segment of ureter which proximally and centrally has a diameter of 0.5 cm, up to 0.6 cm at the distal end. A yellow plastic stent is present in the lumen of the ureter. The ureter is opened and the urothelium is tan and smooth. At the pelvis friable tumor is present in the renal pelvis arising from the central calix. The kidney is bivalved to reveal a finely granular tan-white neoplasm occupying the superior pole calix and extending into the middle pole calix. This neoplasm overall measures 3.7 x 3.2 x 3.2 cm. It is approximately 1 cm from Gerota's fascia and 1.5 cm from the renal hilar vascular margin. It involves the upper pole and central pole calices. The inferior pole calix appears uninvolved. The renal parenchyma is otherwise reddish brown and cortical thickness is 0.6 cm. There are no obvious lymph nodes in the perinephric adipose tissue. Representative sections are submitted. Section summary: A1) surgical margin, renal artery, renal vein and ureter, A2) Gerota's fascia, A3) distal ureter, A4) mid and proximal ureter, A5) ureteropelvic junction, A6-A8) sections of tumor, A9) tumor in renal pelvis, A10) uninvolved kidney. [REDACTED]

Microscopic Description:

Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file d7a593c1-177b-4d79-b7af-4001f6d250cb (TCGA-A4-7287.1AD2078D-58F2-4D51-98C1-3065EF8E6AC2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).